Somatic mutation profile of tumor specimen TARGET-10-PASKAD-09A (aliquot TARGET-10-PASKAD-09A-01D) from TARGET case TARGET-10-PASKAD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,809 days).
Specimen TARGET-10-PASKAD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6e1dc6-140f-481f-b33a-4fbe199a4022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKAD-10A (Blood Derived Normal), aliquot TARGET-10-PASKAD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df571f29-82ea-4fa0-bfe9-6e88a5227bf6

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 2, 5'Flank 2, In Frame Del 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP1 | c.3655A>G p.K1219E (on ENST00000620786 / NM_001247997.1; = p.K1208E on NM_002956.2) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56807185; called by muse, mutect2, varscan2
- CXXC1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV53276410; called by muse, mutect2, varscan2
- EFEMP2 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV57261301; called by muse, mutect2, varscan2
- EPHB3 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771992201, COSV57808554; called by muse, mutect2, varscan2
- FHDC1 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as rs757283743, COSV52602425; called by muse, mutect2, varscan2
- FRAS1 | c.4463C>A p.S1488Y | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV53638598, COSV53659191; called by muse, mutect2, varscan2
- FREM2 | c.7153G>A p.D2385N | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs777183201, COSV54848566; called by muse, mutect2, varscan2
- HDAC1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61482302; called by muse, mutect2, varscan2
- HYAL4 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV56139967; called by muse, mutect2
- KMT2D | c.4419-2A>G p.X1473_splice | Splice Site (SNP) | VAF 41/87 reads (47%) | catalogued as COSV56475940; called by muse, mutect2, varscan2
- NLRP12 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV60753207; called by muse, mutect2, varscan2
- NRG2 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs368980909; called by muse, mutect2, varscan2
- RIMS1 | c.3088C>G p.R1030G | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV53446586, COSV53477554; called by muse, mutect2, varscan2
- RRAGB | c.764T>G p.F255C (on ENST00000262850 / NM_016656.4; = p.F227C on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53331171; called by muse, mutect2, varscan2
- SLCO2B1 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV56938632; called by muse, mutect2, varscan2
- WFDC6 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as COSV60549341; called by muse, mutect2, varscan2
- PTEN | c.699_710delinsGCCTTC p.R234_K237delinsPS | In Frame Del (DEL) | VAF 23/105 reads (22%) | called by pindel, varscan2*
- USP7 | c.542_543del p.K181Rfs*5 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | called by mutect2, varscan2
- ADAMTS2 | c.1080C>T p.H360= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs777406209; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANK1 | c.4458C>T p.S1486= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs200752263; called by muse, mutect2, varscan2
- CEMIP2 | c.3534G>A p.P1178= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs142314012, COSV65487935; called by muse, mutect2, varscan2
- FGF6 | c.606T>C p.T202= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- KRT37 | c.331C>T p.L111= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs144310321; called by muse, mutect2, varscan2
- AL590677.1 | chr10:13526139 ins A | 5'Flank (INS) | VAF 103/262 reads (39%) | catalogued as rs1483993885; called by mutect2, varscan2
- MAP2 | c.455-1975G>T | Intron (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- OR4F17 | chr19:107476 C>T | 5'Flank (SNP) | VAF 20/126 reads (16%) | catalogued as rs1435831754; called by mutect2, varscan2
- TATDN1 | c.664+137T>A | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
